MMRF case MMRF_2203 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/0b64552e-7610-446f-aa2d-79b10e034e13

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 58 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 58.7 years (21,434 days); ISS stage: I; Days to last known disease status: 144 days; Days to last follow up: 144 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 369 mg/dL; Immunoglobulin G 4.57 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 3.2 µg/mL; Lactate Dehydrogenase 6.9 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 11.4 ×10⁹/L; Absolute Neutrophil 9.9 ×10⁹/L; Platelets 237 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 10.8 mmol/L; C-Reactive Protein 1 mg/dL.
- Day 87 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.89 mg/dL; Immunoglobulin G 4.42 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 8.45 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.1 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 9.41 mmol/L.
- Day 144 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.68 mg/dL; Immunoglobulin G 5.16 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.11 g/L; Lactate Dehydrogenase 8.42 µkat/L; Hemoglobin 7.5 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.2 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 9.9 mmol/L.

Other clinical attributes
- Day -4: Weight: 70 kg; Height: 165 cm.

Biospecimens (2 samples)
- Sample MMRF_2203_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_2203_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
